Surgical pathology report (de-identified scan), TCGA case TCGA-06-0148, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0148-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, SITE NOT SPECIFIED, EXCISIONAL BIOPSIES: GLIOBLASTOMA
MULTIFORME. MIB-1 PROLIFERATION INDEX: 14%.

SEE COMMENT.

Operation/Specimen: Brain.

Clinical History and Pre-Op Dx [REDACTED] with large heterogenous
brain tumor. Past history of prostate cancer.

GROSS PATHOLOGY:

A. Received fresh, two fragments, 1.5 cm across in aggregate. Semi-
firm, tannish-brown, focal necrosis. In total #1 and 2.

INTRAOPERATIVE CONSULTATION: Brain, smears: Spindle cell neoplasm
(Glioma vs sarcoma, no carcinoma).

B.

SPECIMEN: Brain tumor.

FIXATIVE: None.

GENERAL: A 4.3 x 3.3 x 1.0 cm. aggregate of brown-tan brain
tissue with red clotted blood.

SECTIONS: X1-X3 - all submitted.
[REDACTED]

SPECIAL STAINS: Snook's reticulum, Masson's trichrome, and
immunoperoxidase methods for GFAP, factor VIII, and MIB-1 were
performed on sections from block #x1.

The Snook's and Masson's demonstrate reticulin fibers and collagen only
in perivascular areas, and the GFAP demonstrates gliofibrilogenesis by
the tumor cells, changes are present even in the pseudosarcomatous
areas. With the MIB-1a proliferation index of 14% is determined is the
more active areas. The factor VIII highlights the microvascular
cellular proliferation.

COMMENT: The neoplasm is a glioblastoma multiforme with focal
pseudosarcomatous zones.
[REDACTED]

[page 2 of 2]
[REDACTED]

TISSUE COMMITTEE CODE: [REDACTED]

ICD9: 191.9
[REDACTED]

Source: NCI Genomic Data Commons file 53742fde-5e99-4f53-a860-2d632f56127f (TCGA-06-0148.4F46FCB4-A2F4-4EEA-A62A-4BAEDEF21D69.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).